Somatic mutation profile of tumor specimen BA2715D (aliquot aq-BA2715D) from BEATAML1.0 case 2192, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.5 years (29,759 days).
Specimen BA2715D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 370929d5-a934-4e4a-a430-1793dc8a456b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2980D (Solid Tissue Normal), aliquot aq-BA2980D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f66a893-7a0a-4a27-b3e4-08af8619a951

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Nonsense Mutation 2, 3'UTR 2, Silent 2, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD1 | c.6521_6523del p.F2174del | In Frame Del (DEL) | VAF 27/58 reads (47%) | catalogued as rs587784206; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 66/172 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBLN2 | c.1942G>T p.G648C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.502); catalogued as rs1045790018, COSV55483624; called by muse, mutect2, varscan2
- GYPC | c.160C>G p.P54A | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV52146059; called by muse, mutect2
- MUC22 | c.4633G>A p.V1545I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0.125); catalogued as rs929540951; called by muse, mutect2
- NLRP3 | c.2932G>A p.D978N | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.097); catalogued as COSV100275358; called by muse, mutect2, varscan2
- NR1H4 | c.1276C>T p.L426F (on ENST00000551379 / NM_001206993.2; = p.L412F on NM_005123.4) | Missense Mutation (SNP) | VAF 75/213 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51849822, COSV51850320; called by muse, mutect2, varscan2
- SLC4A3 | c.1958C>T p.T653M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs201680260; called by muse, mutect2, varscan2
- TP53 | c.617del p.L206Wfs*41 | Frame Shift Del (DEL) | VAF 56/227 reads (25%) | catalogued as COSV52853973; called by mutect2, pindel, varscan2
- XIRP1 | c.3176G>A p.R1059Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs142701163, COSV100453738; called by muse, mutect2, varscan2
- BAIAP3 | c.2857G>C p.A953P | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HDHD2 | c.154_158dup p.Q54Afs*6 | Frame Shift Ins (INS) | VAF 29/161 reads (18%) | called by mutect2, pindel, varscan2
- KCNH7 | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- MYO15B | c.3266A>C p.D1089A | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PUM1 | c.2440T>G p.S814A | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- REXO1 | c.3239C>T p.T1080M | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIAM1 | c.3754C>T p.Q1252* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- ZNF518B | c.3091T>A p.S1031T | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ZNF644 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ADAM2 | c.843C>A p.T281= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as rs370082987; called by muse, mutect2, varscan2
- FSCN3 | c.366C>T p.D122= | Silent (SNP) | VAF 47/106 reads (44%) | catalogued as rs960337966; called by muse, mutect2, varscan2
- DDX41 | c.*970C>G | 3'UTR (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- TP53TG3D | c.*470A>G | 3'UTR (SNP) | VAF 31/47 reads (66%) | catalogued as rs747673420; called by mutect2, varscan2
- UBE2DNL | n.456G>A | RNA (SNP) | VAF 12/18 reads (67%) | called by muse, mutect2, varscan2
